Somatic mutation profile of tumor specimen C3L-01598-02 (aliquot CPT0091660009) from CPTAC case C3L-01598, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 73.1 years (26,697 days).
Specimen C3L-01598-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a3f41fad-c3b8-4bb5-aad7-dbf2bed72557.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01598-31 (Blood Derived Normal), aliquot CPT0093640002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8674c1e5-24e5-4ef7-be16-f9e658483f89

The open-access MAF lists 60 somatic variants for this specimen: 41 protein-altering or splice-affecting, 13 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 13, Intron 3, RNA 2, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 64/407 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.476C>A p.A159D | Missense Mutation (SNP) | VAF 32/332 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52674926, COSV52693942, COSV52759722; called by muse, mutect2
- ABCC1 | c.2572C>G p.R858G | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs1364303106; called by muse, mutect2
- ASH1L | c.680G>A p.C227Y | Missense Mutation (SNP) | VAF 45/392 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as rs1317097485; called by muse, mutect2, varscan2
- CDC14C | c.356G>A p.R119Q (on ENST00000428251; = p.R12Q on NM_152627.3) | Missense Mutation (SNP) | VAF 19/174 reads (11%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs762798999; called by muse, varscan2
- CERS3 | c.841T>C p.F281L | Missense Mutation (SNP) | VAF 18/177 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs769131621; called by muse, mutect2
- COG1 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs1346003642; called by muse, mutect2
- CPN1 | c.1328C>T p.A443V | Missense Mutation (SNP) | VAF 52/622 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs758222936; called by muse, mutect2
- CTPS2 | c.763G>A p.V255M | Missense Mutation (SNP) | VAF 13/241 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as COSV100826980; called by muse, mutect2
- DOCK2 | c.3685G>A p.D1229N | Missense Mutation (SNP) | VAF 19/325 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV56959162; called by muse, mutect2
- DPP6 | c.2564C>G p.T855R (on ENST00000377770 / NM_001364500.2; = p.T793R on NM_001936.5) | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0.024); catalogued as COSV100124930; called by muse, mutect2
- ENPP3 | c.1297G>A p.D433N | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0.009); catalogued as rs1392167820; called by muse, mutect2
- FLACC1 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 26/292 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs144590707; called by muse, mutect2
- GPR22 | c.833G>A p.R278K | Missense Mutation (SNP) | VAF 23/321 reads (7%) | SIFT tolerated (0.92); PolyPhen benign (0.091); catalogued as COSV104396726; called by muse, mutect2
- GRID2 | c.1537G>C p.V513L | Missense Mutation (SNP) | VAF 30/292 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV99941067; called by muse, mutect2
- IRX1 | c.1409C>T p.T470M | Missense Mutation (SNP) | VAF 30/382 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs369886565, COSV57358201; called by muse, mutect2
- KRTAP4-7 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 42/480 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as rs1210310178, COSV66951250, COSV66952261; called by muse, mutect2
- LNX2 | c.1033C>T p.R345W | Missense Mutation (SNP) | VAF 45/371 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs745613572, COSV60338718; called by muse, mutect2, varscan2
- OR10G8 | c.542C>T p.P181L | Missense Mutation (SNP) | VAF 30/348 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as rs776182491, COSV101461769, COSV70909383; called by muse, mutect2
- RNGTT | c.1228G>A p.V410I | Missense Mutation (SNP) | VAF 26/286 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.13); catalogued as rs772588621; called by muse, mutect2
- SLC6A17 | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 30/324 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as rs770557467, COSV58994343, COSV58996157; called by muse, mutect2
- TRANK1 | c.6512G>A p.R2171H | Missense Mutation (SNP) | VAF 29/273 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs370553712; called by muse, mutect2, varscan2
- TRPV6 | c.1087C>T p.R363W | Missense Mutation (SNP) | VAF 17/183 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs375745559, COSV63894637; called by muse, mutect2
- ADAMTSL3 | c.3959G>T p.R1320L | Missense Mutation (SNP) | VAF 16/227 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.107); called by muse, mutect2
- AMPH | c.1215G>T p.Q405H | Missense Mutation (SNP) | VAF 22/284 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.942); called by muse, mutect2
- ARHGAP40 | c.124A>G p.R42G | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2
- ARHGEF10L | c.3649C>T p.P1217S | Missense Mutation (SNP) | VAF 13/204 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- ATP6V0A2 | c.498G>A p.M166I | Missense Mutation (SNP) | VAF 23/338 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.216); called by muse, mutect2
- CARMIL1 | c.3361G>A p.E1121K | Missense Mutation (SNP) | VAF 34/376 reads (9%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.092); called by muse, mutect2
- CDKN2A | c.182_201del p.E61Gfs*52 | Frame Shift Del (DEL) | VAF 32/372 reads (9%) | called by mutect2, pindel
- DNAH6 | c.3892G>C p.A1298P | Missense Mutation (SNP) | VAF 31/374 reads (8%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.82); called by muse, mutect2
- ELAPOR1 | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 12/224 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FLNC | c.1901A>C p.E634A | Missense Mutation (SNP) | VAF 29/342 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2
- GEMIN5 | c.703C>T p.P235S | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.183); called by muse, mutect2
- GLB1L3 | c.1763C>A p.T588N | Missense Mutation (SNP) | VAF 25/494 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- LRRC36 | c.1531G>A p.A511T | Missense Mutation (SNP) | VAF 16/314 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2
- MYH15 | c.3940T>C p.S1314P | Missense Mutation (SNP) | VAF 23/334 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- RFX8 | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 34/450 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TTN | c.12434T>A p.V4145D (on ENST00000591111; = p.V4099D on NM_003319.4) | Missense Mutation (SNP) | VAF 28/506 reads (6%) | called by muse, mutect2
- ULK4 | c.2439G>T p.E813D | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- ZNF644 | c.2009A>G p.Q670R | Missense Mutation (SNP) | VAF 52/752 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.272); called by muse, mutect2
- ACACA | c.4392C>T p.I1464= | Silent (SNP) | VAF 26/453 reads (6%) | called by muse, mutect2
- AHNAK | c.16242T>C p.S5414= | Silent (SNP) | VAF 22/269 reads (8%) | called by muse, mutect2
- ALPI | c.1365C>T p.D455= | Silent (SNP) | VAF 53/292 reads (18%) | catalogued as COSV55015571; called by muse, mutect2, varscan2
- FICD | c.840G>A p.S280= | Silent (SNP) | VAF 24/318 reads (8%) | catalogued as rs375100196; called by muse, mutect2
- HMCN1 | c.16893C>T p.S5631= | Silent (SNP) | VAF 24/298 reads (8%) | catalogued as rs200759463; called by muse, mutect2
- IRX4 | c.1242G>A p.P414= | Silent (SNP) | VAF 14/129 reads (11%) | catalogued as rs1306931783, COSV51473850; called by muse, mutect2, varscan2
- MUC17 | c.7149C>T p.D2383= | Silent (SNP) | VAF 16/244 reads (7%) | catalogued as rs138267850, COSV100075844, COSV60305969; called by muse, mutect2
- NPHS1 | c.3336C>T p.N1112= | Silent (SNP) | VAF 46/620 reads (7%) | catalogued as rs1053234526, COSV62289633; called by muse, mutect2
- NR0B1 | c.288G>A p.A96= | Silent (SNP) | VAF 33/416 reads (8%) | catalogued as COSV66764071; called by muse, mutect2
- PTCHD4 | c.1923C>T p.I641= | Silent (SNP) | VAF 34/390 reads (9%) | catalogued as rs1159948461, COSV59778738, COSV59780961; called by muse, mutect2
- PXDN | c.2787G>T p.L929= | Silent (SNP) | VAF 15/154 reads (10%) | called by muse, mutect2, varscan2
- SLC46A1 | c.378C>T p.L126= | Silent (SNP) | VAF 38/313 reads (12%) | catalogued as rs375678730; called by muse, mutect2, varscan2
- SORCS3 | c.315C>T p.A105= | Silent (SNP) | VAF 18/167 reads (11%) | called by muse, mutect2
- BAIAP2 | chr17:81032954 G>A | 5'Flank (SNP) | VAF 17/219 reads (8%) | called by muse, mutect2
- FXYD5 | c.199+1140T>G | Intron (SNP) | VAF 15/253 reads (6%) | called by muse, mutect2
- LINC00452 | n.704G>A | RNA (SNP) | VAF 20/217 reads (9%) | catalogued as rs772152045; called by muse, mutect2
- PDZRN4 | c.844-68478G>C | Intron (SNP) | VAF 24/374 reads (6%) | called by muse, mutect2
- SPOPL | c.480+1775G>T | Intron (SNP) | VAF 11/87 reads (13%) | called by muse, mutect2, varscan2
- SSX6P | n.74C>T | RNA (SNP) | VAF 15/266 reads (6%) | catalogued as rs150874433; called by muse, mutect2
